Somatic mutation profile of tumor specimen ALCH-AFFK-TTP1-A (aliquot ALCH-AFFK-TTP1-A-1-0-D-A667-36) from ALCHEMIST case ALCH-AFFK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.9 years (25,885 days).
Specimen ALCH-AFFK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70c96559-ef6c-43fe-bdbf-fd3514999539.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFFK-NB1-A (Blood Derived Normal), aliquot ALCH-AFFK-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b42e7be8-d610-4b72-bba0-8152d4bf36a7

The open-access MAF lists 50 somatic variants for this specimen: 39 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 7, Intron 2, Splice Region 1, 3'UTR 1, Splice Site 1, RNA 1, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 141/511 reads (28%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ASTN1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as rs1369516870, COSV56064899, COSV56071491; called by muse, mutect2, varscan2
- CHST6 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.727); catalogued as rs1193863364; called by muse, mutect2, varscan2
- LMO7 | c.755T>C p.L252S (on ENST00000357063; = p.L267S on NM_005358.5) | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1165833215; called by muse, mutect2, varscan2
- NBEA | c.5615C>G p.A1872G | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV59769530, COSV59772961; called by muse, mutect2
- PARP4 | c.2228T>C p.V743A | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs574930813; called by muse, mutect2, varscan2
- PRKAG2 | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs748790230; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SKIV2L | c.1453G>C p.V485L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs528764402; called by muse, mutect2
- SLC8A3 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1381393122, COSV63520241; called by muse, mutect2
- STX16 | c.763A>G p.R255G (on ENST00000371141 / NM_001001433.3; = p.R234G on NM_003763.6) | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs535191941; called by muse, mutect2, varscan2
- TRPS1 | c.3616G>T p.D1206Y (on ENST00000220888 / NM_001330599.2; = p.D1219Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/1014 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1314268744; called by muse, mutect2
- TTN | c.56390T>C p.I18797T (on ENST00000591111; = p.I11373T on NM_003319.4) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | PolyPhen benign (0.033); catalogued as rs756962314; called by muse, mutect2, varscan2
- ZC3H7B | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs745958198, COSV60962962; called by muse, mutect2, varscan2
- ZNF341 | c.2116A>G p.T706A (on ENST00000375200 / NM_001282935.1; = p.T699A on NM_032819.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV61010091; called by muse, varscan2
- ZNF341 | c.2129A>G p.K710R (on ENST00000375200 / NM_001282935.1; = p.K703R on NM_032819.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1227233943; called by muse, varscan2
- ABL2 | c.1469A>G p.D490G (on ENST00000502732 / NM_007314.4; = p.D475G on NM_005158.5) | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.322); called by muse, mutect2
- ACP2 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- APP | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHRNA1 | c.1334A>C p.K445T (on ENST00000261007 / NM_001039523.3; = p.K420T on NM_000079.4) | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DNM3 | c.1540A>T p.N514Y | Missense Mutation (SNP) | VAF 61/428 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, varscan2
- EDEM2 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- FOXN2 | c.771A>G p.E257= | Splice Region (SNP) | VAF 47/368 reads (13%) | called by muse, varscan2
- GABRA2 | c.530C>A p.A177D | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.424); called by muse, mutect2
- GEMIN5 | c.2466C>G p.N822K | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GPM6A | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 34/654 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2
- GPR158 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRK5 | c.419A>T p.E140V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- HERC5 | c.689-1G>A p.X230_splice | Splice Site (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- IL2RG | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- KCNJ2 | c.929_930del p.Q310Lfs*3 | Frame Shift Del (DEL) | VAF 25/227 reads (11%) | called by mutect2, pindel, varscan2
- RAB1A | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RPS6KA2 | c.1187C>G p.P396R | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- ST8SIA5 | c.651C>G p.I217M | Missense Mutation (SNP) | VAF 30/178 reads (17%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK38 | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SVIL | c.3226C>G p.Q1076E (on ENST00000355867 / NM_021738.3; = p.Q650E on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.076); called by muse, mutect2
- TMEM135 | c.59A>T p.H20L | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBC | c.725C>G p.T242S | Missense Mutation (SNP) | VAF 115/405 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ZNF182 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF30 | c.1000dup p.H334Pfs*8 | Frame Shift Ins (INS) | VAF 31/167 reads (19%) | called by mutect2, pindel, varscan2
- AIPL1 | c.174C>T p.P58= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- ARMH4 | c.2112A>G p.L704= | Silent (SNP) | VAF 32/228 reads (14%) | called by muse, mutect2, varscan2
- FCGR2A | c.522C>T p.I174= (on ENST00000271450 / NM_001136219.3; = p.I173= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/662 reads (4%) | catalogued as COSV54840648; called by muse, mutect2
- FLI1 | c.1119G>A p.P373= | Silent (SNP) | VAF 78/534 reads (15%) | catalogued as rs768469579, COSV55644747; called by muse, mutect2, varscan2
- GTF2I | c.177T>G p.T59= | Silent (SNP) | VAF 69/376 reads (18%) | called by muse, mutect2, varscan2
- MYADML2 | c.300G>A p.A100= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs1029653298, COSV57998701; called by muse, mutect2
- OR5D18 | c.90G>C p.L30= | Silent (SNP) | VAF 7/200 reads (4%) | called by muse, mutect2
- AP1S3 | c.*39_*42del | 3'UTR (DEL) | VAF 8/30 reads (27%) | catalogued as rs200257231; called by pindel, varscan2
- CMAHP | n.1443T>C | RNA (SNP) | VAF 19/460 reads (4%) | catalogued as rs1463022421; called by muse, mutect2
- HHLA2 | c.1225-33C>G | Intron (SNP) | VAF 61/184 reads (33%) | called by muse, mutect2, varscan2
- SULT1A2 | c.274+32_274+34del | Intron (DEL) | VAF 16/178 reads (9%) | called by pindel, varscan2
